Somatic mutation profile of tumor specimen MMRF_1700_2_BM_CD138pos (aliquot MMRF_1700_2_BM_CD138pos_T1_KHS5U_L11613) from MMRF case MMRF_1700, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.8 years (27,692 days).
Specimen MMRF_1700_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06b5908c-4a64-458a-8cbc-00e0cb9ecd0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1700_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1700_1_PB_Whole_C3_KBS5U_L05393; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82fdf4cb-15a0-4eb3-b4f4-ce6d85b8f692

The open-access MAF lists 142 somatic variants for this specimen: 53 protein-altering or splice-affecting, 24 silent, 65 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, 3'UTR 36, Silent 24, Intron 18, Nonsense Mutation 4, 5'UTR 4, Frame Shift Del 3, 3'Flank 3, 5'Flank 2, RNA 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.17-2A>T p.X6_splice | Splice Site (SNP) | VAF 9/10 reads (90%) | hotspot (GDC flag); catalogued as COSV63309299, COSV63309333; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 46/127 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABCC2 | c.369G>T p.W123C | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs202137941; called by muse, mutect2, varscan2
- ADARB2 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs377136355; called by muse, mutect2, varscan2
- CDCA7L | c.230C>A p.T77N | Missense Mutation (SNP) | VAF 113/298 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.43); catalogued as rs776912112; called by muse, mutect2, varscan2
- CDK11A | c.1889C>A p.S630* (on ENST00000378633 / NM_001313896.2; = p.S627* on NM_024011.4) | Nonsense Mutation (SNP) | VAF 101/229 reads (44%) | catalogued as rs757293035, COSV52307726, COSV99319203; called by muse, mutect2, varscan2
- CDS1 | c.238T>C p.S80P | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs775262819; called by muse, mutect2, varscan2
- CEP290 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV58354584; called by muse, mutect2, varscan2
- CWF19L2 | c.2344C>G p.P782A | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1336851852, COSV56518866; called by muse, mutect2, varscan2
- ERBB4 | c.367T>A p.Y123N | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53508555; called by muse, mutect2, varscan2
- HOXD11 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as rs1395005679; called by muse, mutect2, varscan2
- IGHV2-70 | c.356T>C p.I119T | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs777686921; called by muse, varscan2
- IGKJ4 | c.23A>T p.K8M | Missense Mutation (SNP) | VAF 67/112 reads (60%) | PolyPhen benign (0.27); catalogued as rs147540982; called by muse, varscan2
- IP6K3 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs537814047; called by muse, mutect2, varscan2
- KCNMA1 | c.3149C>T p.T1050M (on ENST00000286628 / NM_001161352.2; = p.T992M on NM_002247.4) | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs915080941; called by muse, mutect2, varscan2
- KLF2 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1404814458, COSV50179850; called by muse, mutect2, varscan2
- MED15 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.12); catalogued as rs774118258; called by muse, mutect2, varscan2
- NRXN2 | c.3175C>T p.R1059W | Missense Mutation (SNP) | VAF 64/227 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200881363, COSV55454740; called by muse, mutect2, varscan2
- PCDHB5 | c.318C>A p.F106L | Missense Mutation (SNP) | VAF 13/336 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV50660789; called by muse, mutect2
- PPP1R1C | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 62/178 reads (35%) | catalogued as rs1489694914; called by muse, mutect2, varscan2
- SORCS2 | c.2810C>T p.T937M | Missense Mutation (SNP) | VAF 95/198 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs372065575; called by muse, mutect2, varscan2
- USP26 | c.1836dup p.G613Rfs*6 | Frame Shift Ins (INS) | VAF 73/224 reads (33%) | catalogued as rs749830910; called by mutect2, varscan2
- WDR6 | c.386T>C p.I129T | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs774083749; called by muse, mutect2, varscan2
- ADD1 | c.1843C>T p.P615S | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AL645922.1 | c.1607A>G p.Q536R | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- CARMIL2 | c.3565G>A p.G1189S | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC141 | c.3986A>G p.E1329G | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CCDC168 | c.13838C>A p.T4613K | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- CDK8 | c.1061C>G p.P354R | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CFAP65 | c.5230A>C p.K1744Q | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.314); called by muse, mutect2
- CNTN5 | c.589T>G p.F197V | Missense Mutation (SNP) | VAF 87/294 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- FAM120AOS | c.412T>C p.F138L | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- GAD2 | c.520+4T>C | Splice Region (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- GDF9 | c.1203G>A p.M401I | Missense Mutation (SNP) | VAF 54/210 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- GIPC3 | c.2669C>G p.T890S | Missense Mutation (SNP) | VAF 72/367 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IWS1 | c.988_995del p.D330Qfs*6 | Frame Shift Del (DEL) | VAF 104/150 reads (69%) | called by mutect2, pindel, varscan2
- KBTBD11 | c.1625G>A p.R542H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- KIAA1958 | c.2101T>C p.S701P | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- KIT | c.1412A>T p.K471M | Missense Mutation (SNP) | VAF 87/189 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MAT2B | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- MPDZ | c.4183G>T p.A1395S | Missense Mutation (SNP) | VAF 102/273 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- NID2 | c.3951C>G p.Y1317* | Nonsense Mutation (SNP) | VAF 82/214 reads (38%) | called by muse, mutect2, varscan2
- NOBOX | c.1663G>T p.E555* | Nonsense Mutation (SNP) | VAF 30/77 reads (39%) | called by muse, mutect2, varscan2
- PCDHA3 | c.1741G>A p.V581M | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- PFKL | c.862G>C p.G288R | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- PGGHG | c.205_206delinsT p.P69Lfs*8 | Frame Shift Del (DEL) | VAF 46/216 reads (21%) | called by pindel, varscan2*
- PGRMC2 | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAMHD1 | c.1424C>A p.S475Y | Missense Mutation (SNP) | VAF 236/446 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SIGLEC10 | c.848del p.P283Lfs*4 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | called by pindel, varscan2
- SLC9A2 | c.1051G>A p.V351I | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- VPS37D | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- ZNF648 | c.433C>A p.L145I | Missense Mutation (SNP) | VAF 85/343 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZNF804A | c.2949G>C p.K983N | Missense Mutation (SNP) | VAF 92/262 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ASTE1 | c.963G>A p.L321= | Silent (SNP) | VAF 91/299 reads (30%) | called by muse, mutect2, varscan2
- BAIAP2L2 | c.1236C>T p.N412= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as COSV57635065; called by mutect2, varscan2
- BHLHE41 | c.1126C>T p.L376= | Silent (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
- FBXW12 | c.1338T>C p.L446= | Silent (SNP) | VAF 77/231 reads (33%) | called by muse, mutect2, varscan2
- FILIP1 | c.228C>A p.S76= | Silent (SNP) | VAF 54/111 reads (49%) | catalogued as COSV52732404; called by muse, mutect2, varscan2
- FLG2 | c.4797C>T p.Y1599= | Silent (SNP) | VAF 325/553 reads (59%) | catalogued as rs747254831, COSV66167542; called by muse, mutect2, varscan2
- IGHV2-70 | c.339G>A p.T113= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as rs376111067; called by muse, varscan2
- IGHV2-70 | c.186A>T p.P62= | Silent (SNP) | VAF 60/142 reads (42%) | catalogued as rs997215308; called by muse, varscan2
- INSRR | c.321G>A p.T107= | Silent (SNP) | VAF 124/190 reads (65%) | catalogued as rs377729626; called by muse, mutect2, varscan2
- KHNYN | c.429C>T p.S143= | Silent (SNP) | VAF 43/107 reads (40%) | called by muse, mutect2, varscan2
- LRRC28 | c.277C>T p.L93= | Silent (SNP) | VAF 28/354 reads (8%) | called by muse, mutect2
- LYST | c.5001G>T p.L1667= | Silent (SNP) | VAF 20/123 reads (16%) | called by muse, mutect2, varscan2
- MAP6 | c.1311G>A p.A437= | Silent (SNP) | VAF 37/120 reads (31%) | catalogued as rs200607557; called by muse, mutect2, varscan2
- OTX2 | c.225C>A p.I75= (on ENST00000408990 / NM_172337.3; = p.I83= on NM_021728.4) | Silent (SNP) | VAF 58/176 reads (33%) | called by muse, mutect2, varscan2
- PCDH7 | c.216C>T p.S72= | Silent (SNP) | VAF 124/329 reads (38%) | catalogued as COSV62336590; called by muse, mutect2, varscan2
- PRRT3 | c.2103G>A p.A701= | Silent (SNP) | VAF 36/69 reads (52%) | called by muse, mutect2, varscan2
- SIX4 | c.1119C>G p.P373= | Silent (SNP) | VAF 87/211 reads (41%) | called by muse, mutect2, varscan2
- TPTE2 | c.777C>T p.N259= (on ENST00000400230 / NM_199254.2; = p.N182= on NM_130785.3) | Silent (SNP) | VAF 44/108 reads (41%) | called by muse, mutect2, varscan2
- TRPM8 | c.1980G>A p.A660= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as rs145636954; called by muse, mutect2, varscan2
- UBAP2 | c.546G>C p.G182= | Silent (SNP) | VAF 94/358 reads (26%) | called by muse, mutect2, varscan2
- ZBTB7A | c.1191G>A p.L397= | Silent (SNP) | VAF 88/298 reads (30%) | catalogued as rs947443348; called by muse, mutect2, varscan2
- ZNF300 | c.1665A>G p.G555= | Silent (SNP) | VAF 64/257 reads (25%) | called by muse, mutect2, varscan2
- ZNF431 | c.1134C>A p.G378= | Silent (SNP) | VAF 30/140 reads (21%) | called by muse, mutect2, varscan2
- ZPLD1 | c.927T>A p.L309= (on ENST00000466937 / NM_001329788.1; = p.L325= on NM_175056.2) | Silent (SNP) | VAF 87/319 reads (27%) | called by muse, mutect2, varscan2
- ABL1 | c.*1070G>A | 3'UTR (SNP) | VAF 39/170 reads (23%) | called by muse, mutect2, varscan2
- ANP32BP3 | n.656G>A | RNA (SNP) | VAF 78/216 reads (36%) | catalogued as rs984356872; called by muse, mutect2, varscan2
- ARHGEF10 | c.*281G>A | 3'UTR (SNP) | VAF 29/75 reads (39%) | catalogued as rs1467232149; called by muse, mutect2, varscan2
- ATF6 | c.*4261A>C | 3'UTR (SNP) | VAF 14/82 reads (17%) | called by muse, mutect2, varscan2
- ATP7B | c.2866-60G>C | Intron (SNP) | VAF 19/28 reads (68%) | called by muse, mutect2, varscan2
- ATP8B4 | c.2036-39A>G | Intron (SNP) | VAF 44/102 reads (43%) | called by muse, mutect2
- BCL7A | chr12:122021407 A>T | 5'Flank (SNP) | VAF 71/89 reads (80%) | catalogued as rs566164810, COSV55850178; called by muse, mutect2, varscan2
- BGN | c.*304C>T | 3'UTR (SNP) | VAF 59/178 reads (33%) | catalogued as rs1030280353; called by muse, mutect2, varscan2
- BMP15 | chrX:50905834 G>T | 5'Flank (SNP) | VAF 51/66 reads (77%) | called by muse, mutect2, varscan2
- C4orf33 | c.-553dup | 5'UTR (INS) | VAF 29/88 reads (33%) | called by mutect2, varscan2
- C9orf135 | c.449+81A>C | Intron (SNP) | VAF 124/607 reads (20%) | called by muse, mutect2, varscan2
- CALB1 | c.*993A>C | 3'UTR (SNP) | VAF 21/83 reads (25%) | called by muse, mutect2, varscan2
- CRACR2A | c.*286A>C | 3'UTR (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2
- CTSC | c.318+10558del | Intron (DEL) | VAF 19/91 reads (21%) | called by mutect2, pindel, varscan2
- DES | c.*347C>T | 3'UTR (SNP) | VAF 43/100 reads (43%) | called by muse, mutect2, varscan2
- EOGT | c.*992T>C | 3'UTR (SNP) | VAF 11/13 reads (85%) | called by muse, mutect2, varscan2
- EOGT | c.*889T>C | 3'UTR (SNP) | VAF 28/37 reads (76%) | called by muse, mutect2, varscan2
- EOGT | c.*770T>C | 3'UTR (SNP) | VAF 17/21 reads (81%) | called by muse, mutect2, varscan2
- FAF1 | c.*1062T>C | 3'UTR (SNP) | VAF 11/71 reads (15%) | catalogued as rs976406059; called by muse, mutect2, varscan2
- FAM219A | c.*338G>A | 3'UTR (SNP) | VAF 76/250 reads (30%) | called by muse, mutect2, varscan2
- FBLN2 | c.*23G>A | 3'UTR (SNP) | VAF 29/72 reads (40%) | catalogued as rs556247082, COSV99851556; called by muse, mutect2, varscan2
- FTHL17 | c.-4C>T | 5'UTR (SNP) | VAF 59/66 reads (89%) | catalogued as rs1315767751, COSV100784395, COSV63266680; called by muse, mutect2, varscan2
- GABRA5 | c.*717G>A | 3'UTR (SNP) | VAF 7/143 reads (5%) | called by muse, mutect2
- GALNT13 | c.1531-3682G>A | Intron (SNP) | VAF 43/154 reads (28%) | called by muse, mutect2, varscan2
- GAS7 | c.886-21G>A | Intron (SNP) | VAF 67/154 reads (44%) | called by muse, mutect2, varscan2
- GZF1 | c.*1613T>G | 3'UTR (SNP) | VAF 42/121 reads (35%) | called by muse, mutect2, varscan2
- HNF4G | chr8:75566024 TTCCCTTAGAAGACATTA>GTTCCCTTAGAAGACATT | 3'Flank (ONP) | VAF 4/50 reads (8%) | called by pindel, varscan2*
- HOXB3 | c.-158-899G>T | Intron (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- IGHV4-39 | c.-29A>C | 5'UTR (SNP) | VAF 16/18 reads (89%) | catalogued as rs369647413; called by muse, varscan2
- KIAA1549 | c.*4480G>A | 3'UTR (SNP) | VAF 104/256 reads (41%) | catalogued as rs1441816050; called by muse, mutect2, varscan2
- LARGE1 | c.*429T>C | 3'UTR (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2, varscan2
- LINC02693 | n.4714G>A | RNA (SNP) | VAF 55/127 reads (43%) | catalogued as rs995990409; called by muse, mutect2, varscan2
- LVRN | c.2757-900G>C | Intron (SNP) | VAF 33/117 reads (28%) | called by muse, mutect2, varscan2
- MAP1B | c.*1679T>A | 3'UTR (SNP) | VAF 29/120 reads (24%) | called by muse, mutect2, varscan2
- MRPL55 | c.-58-59A>T | Intron (SNP) | VAF 90/148 reads (61%) | called by muse, mutect2
- MYCN | c.*325T>C | 3'UTR (SNP) | VAF 24/40 reads (60%) | called by muse, mutect2, varscan2
- NKTR | c.286+775A>T | Intron (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2
- NME8 | c.*6A>G | 3'UTR (SNP) | VAF 96/211 reads (45%) | called by muse, mutect2, varscan2
- NME8 | c.*7T>A | 3'UTR (SNP) | VAF 93/207 reads (45%) | called by muse, mutect2, varscan2
- NTM | c.-298G>A | 5'UTR (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- OAS2 | c.448+31G>A | Intron (SNP) | VAF 22/33 reads (67%) | called by muse, mutect2, varscan2
- PDE1C | c.1892-13417A>T | Intron (SNP) | VAF 22/55 reads (40%) | catalogued as COSV58514490; called by muse, mutect2, varscan2
- PITPNB | c.297+156_297+170del | Intron (DEL) | VAF 24/51 reads (47%) | called by mutect2, pindel, varscan2
- PRKCZ | c.975-19G>A | Intron (SNP) | VAF 61/147 reads (41%) | catalogued as rs757912200; called by muse, mutect2, varscan2
- PTGS2 | c.*1459del | 3'UTR (DEL) | VAF 20/34 reads (59%) | catalogued as rs887190876; called by mutect2, varscan2
- RBM12 | chr20:35649210 T>A | 3'Flank (SNP) | VAF 77/136 reads (57%) | called by muse, mutect2, varscan2
- SDK2 | c.*3556G>A | 3'UTR (SNP) | VAF 62/141 reads (44%) | called by muse, mutect2, varscan2
- SLC30A9 | c.1662+57T>A | Intron (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- SLC38A6 | c.1290+101_1290+102del | Intron (DEL) | VAF 7/10 reads (70%) | called by mutect2, varscan2
- SLC39A10 | c.*30G>T | 3'UTR (SNP) | VAF 11/224 reads (5%) | called by muse, mutect2
- SLC44A1 | c.*1291dup | 3'UTR (INS) | VAF 10/29 reads (34%) | catalogued as rs965525535; called by mutect2, varscan2
- SLC4A2 | c.52-1070C>T | Intron (SNP) | VAF 6/104 reads (6%) | catalogued as rs1172533502; called by muse, mutect2
- SLC5A3 | c.*8103G>A | 3'UTR (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- SPCS3 | c.*502G>C | 3'UTR (SNP) | VAF 53/113 reads (47%) | catalogued as rs908027502; called by muse, mutect2, varscan2
- STEAP4 | c.*1780C>A | 3'UTR (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- TFCP2L1 | c.*2619del | 3'UTR (DEL) | VAF 30/85 reads (35%) | called by mutect2, pindel, varscan2
- TIRAP | c.646+49C>A | Intron (SNP) | VAF 68/238 reads (29%) | called by muse, mutect2, varscan2
- TPPP | c.*1980_*1981insGTCACAGACGAGCAGTCATCGGACTCACCCG | 3'UTR (INS) | VAF 8/56 reads (14%) | called by pindel, varscan2*
- TRAPPC3L | c.*1673G>A | 3'UTR (SNP) | VAF 73/204 reads (36%) | called by muse, mutect2, varscan2
- UBQLN1 | c.*1500C>T | 3'UTR (SNP) | VAF 31/97 reads (32%) | called by muse, mutect2, varscan2
- UBR3 | c.*463_*464insC | 3'UTR (INS) | VAF 27/78 reads (35%) | called by mutect2, varscan2
- UQCRB | c.*5058C>T | 3'UTR (SNP) | VAF 28/68 reads (41%) | catalogued as rs540795518; called by muse, mutect2, varscan2
- USP15 | chr12:62417406 T>C | 3'Flank (SNP) | VAF 29/32 reads (91%) | called by muse, mutect2, varscan2
- ZFAT | c.*162C>T | 3'UTR (SNP) | VAF 72/145 reads (50%) | called by muse, mutect2, varscan2
- ZNF716 | c.*864A>G | 3'UTR (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
